Gene-level copy-number profile of tumor specimen TCGA-JY-A6FB-01A from TCGA case TCGA-JY-A6FB, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.4 years (28,269 days).
Specimen TCGA-JY-A6FB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.bc49c399-3daf-4d43-8d52-4241664899ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JY-A6FB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc120f57-5a87-464c-b72b-c42402831ec6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 2,408; copy number 2: 17,702; copy number 3: 26,960; copy number 4: 11,882; copy number 5: 255; copy number 6: 142; copy number 7: 46; copy number 8: 36; copy number 11: 39; copy number 15: 45; copy number 17: 126; copy number 25: 133; copy number 34: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JY-A6FB-01A-11D-A33D-01): tumor purity 0.64, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:189,666,149–189,666,256, 1 gene: RNA5SP73.
- chr1:246,566,444–246,685,075, 4 genes (within-gene range 0–3): CNST, AL591623.1, AL591623.2, AL591848.2.
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,480,839–22,029,594, 14 genes (within-gene range 0–2): IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr16:78,793,584–78,796,362, 1 gene: AC009141.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 444 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,494,853–47,627,263, 162 genes, copy number 17–34 (broad region; genes not listed).
- chr6:49,565,924–52,087,613, 30 genes, copy number 8 (within-gene range 3–8): CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1, PKHD1, RN7SL580P.
- chr8:123,288,355–127,742,951, 84 genes, copy number 7–11 (broad region; genes not listed).
- chr8:127,795,962–127,796,028, 1 gene, copy number 11: MIR1204.
- chr17:39,173,290–41,865,423, 166 genes, copy number 8–25 (broad region; genes not listed).
- chr17:41,867,581–41,867,736, 1 gene, copy number 25: AC125257.2.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
